Somatic mutation profile of tumor specimen 0DQOFA from CCDI case PBCFID, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.4 years (4,153 days).
Specimen 0DQOFA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ee03275-06ee-4a25-be28-2e7ce1bfd1ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQOF0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85182c5f-d380-44bd-a13b-222fc630f6d9

The open-access MAF lists 16 somatic variants for this specimen: 14 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Nonsense Mutation 4, Silent 1, Splice Region 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.109T>C p.S37P | Missense Mutation (SNP) | VAF 306/779 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs121913228, COSV62688488, COSV62688537, COSV62706597; ClinVar: likely pathogenic; called by muse, varscan2
- DDX3X | c.1592C>T p.T531M (on ENST00000399959; = p.T532M on NM_001356.5) | Missense Mutation (SNP) | VAF 194/1318 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064795387, COSV67863875; ClinVar: pathogenic; called by muse, varscan2
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 337/1130 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, varscan2
- PTCH1 | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 250/792 reads (32%) | catalogued as rs1554702186; ClinVar: pathogenic; called by muse, varscan2
- CREBBP | c.3494G>A p.W1165* | Nonsense Mutation (SNP) | VAF 263/699 reads (38%) | catalogued as CM1414246, COSV52115936; called by muse, varscan2
- MGA | c.2425+1G>A p.X809_splice | Splice Site (SNP) | VAF 110/394 reads (28%) | catalogued as rs940910750; called by muse, varscan2
- PTCH1 | c.1612G>A p.G538R | Missense Mutation (SNP) | VAF 225/659 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1347882326; called by muse, varscan2
- SKA3 | c.*2A>G | Splice Region (SNP) | VAF 126/786 reads (16%) | catalogued as rs1565990292; called by muse, varscan2
- SNX13 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 387/1266 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV68065044; called by muse, varscan2
- SOX5 | c.1782G>A p.W594* | Nonsense Mutation (SNP) | VAF 180/512 reads (35%) | catalogued as COSV58636273; called by muse, varscan2
- ANKRD17 | c.4634C>T p.S1545F | Missense Mutation (SNP) | VAF 332/1075 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- OR7C1 | c.479C>T p.T160I | Missense Mutation (SNP) | VAF 45/436 reads (10%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.703); called by muse, varscan2
- PTCH1 | c.2872G>T p.E958* | Nonsense Mutation (SNP) | VAF 256/736 reads (35%) | called by muse, varscan2
- YLPM1 | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 76/261 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); called by muse, varscan2
- FGR | c.576C>T p.G192= | Silent (SNP) | VAF 200/649 reads (31%) | catalogued as rs779867650, COSV64969508; called by muse, varscan2
- BEAN1 | c.*16G>A | 3'UTR (SNP) | VAF 52/144 reads (36%) | catalogued as rs768010368; called by muse, varscan2
